CPTAC case C3L-02990 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a9cefb0d-5d16-4c54-8c23-22c1bb38a554

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 67.1 years (24,520 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M1b; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; FIGO stage: Stage IB; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 274 days; Progression or recurrence: no; Days to last follow up: 274 days; Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 5.3 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 3; Margin status: Indeterminate.

Follow-up (1 entry)
- Days to follow up: 274 days; ECOG performance status: 0.

Other clinical attributes
- Weight: 53.3 kg; Height: 154.94 cm; BMI: 22.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking onset year: 1974; Tobacco smoking quit year: 2014; Exposure duration years: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02990-08: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 23 days; Initial weight: 285 mg; Time between clamping and freezing: 32 minutes; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02990-28: Section location: Posterior endometrium; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3L-02990-18: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 23 days; Time between clamping and freezing: 32 minutes; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02990-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 23 days; Method of sample procurement: Blood Draw.
